FM case AD8575 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas.
https://portal.gdc.cancer.gov/cases/f61a3ece-0db0-4bc5-8aa4-c8a196b56832

Male, 58.2 years: Urothelial carcinoma, NOS (ICD-O-3 8120/3); specimen biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Tumor.
